Somatic mutation profile of tumor specimen 0DVBVT from CCDI case PBCMGP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 2.8 years (1,035 days).
Specimen 0DVBVT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fba2a4b-1c9c-4801-8720-20922f59d9f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVBVG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9235c6fb-cd9d-4c52-8294-6a99319e141a

The open-access MAF lists 35 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 7, Intron 5, 3'UTR 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.7278G>T p.W2426C | Missense Mutation (SNP) | VAF 54/352 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.894); catalogued as COSV67978964; called by muse, mutect2, varscan2
- IRAG2 | c.3944G>A p.R1315H (on ENST00000636465; = p.R360H on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/742 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs147775174; called by muse, mutect2
- NR5A1 | c.1071G>T p.Q357H | Missense Mutation (SNP) | VAF 59/461 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1387520751; called by muse, mutect2, varscan2
- RELN | c.3712-1G>T p.X1238_splice | Splice Site (SNP) | VAF 30/705 reads (4%) | catalogued as COSV100634496, COSV59040252; called by muse, mutect2
- RGPD4 | c.1775C>A p.S592Y | Missense Mutation (SNP) | VAF 62/886 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61750301; called by muse, mutect2
- SHPRH | c.4858C>T p.R1620* (on ENST00000275233 / NM_001042683.3; = p.R1624* on NM_173082.3) | Nonsense Mutation (SNP) | VAF 76/925 reads (8%) | catalogued as rs1164656828, COSV51614430; called by muse, mutect2
- SLC29A4 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 151/770 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as rs777481698; called by muse, mutect2, varscan2
- TCN1 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 24/914 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as rs1379794935; called by muse, mutect2
- ADAM28 | c.1439G>A p.G480D | Missense Mutation (SNP) | VAF 33/648 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADCY2 | c.2571G>T p.E857D | Missense Mutation (SNP) | VAF 30/870 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- ASZ1 | c.1110A>T p.L370F | Missense Mutation (SNP) | VAF 134/1192 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- COQ6 | c.136G>T p.V46L | Missense Mutation (SNP) | VAF 42/594 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- CRAMP1 | c.3500C>A p.A1167E | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.231); called by muse, varscan2
- KCNH5 | c.1335G>T p.E445D | Missense Mutation (SNP) | VAF 62/594 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LATS2 | c.2352G>T p.K784N | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- NR2F6 | c.1063C>A p.L355M | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR5M1 | c.716C>A p.S239Y | Missense Mutation (SNP) | VAF 113/1914 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); called by muse, mutect2
- PRAMEF20 | c.1240G>T p.A414S | Missense Mutation (SNP) | VAF 33/276 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- RC3H1 | c.2630C>T p.S877F | Missense Mutation (SNP) | VAF 147/680 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SEMA6B | c.1670C>A p.P557Q | Missense Mutation (SNP) | VAF 75/297 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- STX4 | c.397C>A p.Q133K | Missense Mutation (SNP) | VAF 121/356 reads (34%) | SIFT tolerated (1); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- NPHP1 | c.2070C>T p.F690= (on ENST00000393272 / NM_207181.4; = p.F691= on NM_000272.5) | Silent (SNP) | VAF 84/566 reads (15%) | catalogued as rs1274438811; called by muse, varscan2
- OR52J3 | c.117G>T p.V39= | Silent (SNP) | VAF 125/694 reads (18%) | called by muse, varscan2
- OTOG | c.8397G>T p.V2799= | Silent (SNP) | VAF 77/453 reads (17%) | called by muse, mutect2, varscan2
- SAMD9L | c.3534G>A p.E1178= | Silent (SNP) | VAF 112/964 reads (12%) | called by muse, mutect2, varscan2
- SCN10A | c.5064C>A p.T1688= | Silent (SNP) | VAF 24/432 reads (6%) | called by muse, mutect2
- TMEM87B | c.1161G>C p.V387= | Silent (SNP) | VAF 35/600 reads (6%) | called by muse, mutect2
- ZFHX4 | c.5094A>G p.L1698= | Silent (SNP) | VAF 48/1012 reads (5%) | catalogued as COSV51492629; called by muse, mutect2
- FAIM | c.-22-32C>G | Intron (SNP) | VAF 38/218 reads (17%) | called by muse, mutect2, varscan2
- HNRNPH1 | c.398-39A>G | Intron (SNP) | VAF 43/157 reads (27%) | called by muse, mutect2, varscan2
- ITGAX | c.318+48G>T | Intron (SNP) | VAF 34/197 reads (17%) | catalogued as rs1418931609; called by muse, mutect2, varscan2
- LMLN2 | c.1979+29C>A | Intron (SNP) | VAF 28/179 reads (16%) | called by muse, mutect2, varscan2
- NTNG1 | c.*21G>A | 3'UTR (SNP) | VAF 151/429 reads (35%) | catalogued as rs577255487, COSV100903691; called by muse, mutect2, varscan2
- PDGFRA | c.*35G>T | 3'UTR (SNP) | VAF 78/201 reads (39%) | called by muse, mutect2, varscan2
- TRPM1 | c.1197+44G>C | Intron (SNP) | VAF 76/205 reads (37%) | catalogued as rs1199420340; called by muse, mutect2, varscan2
